Somatic mutation profile of cancer-model specimen HCM-BROD-0011-C71-85A (3D Neurosphere, passage 25; aliquot HCM-BROD-0011-C71-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-BROD-0011-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.7 years (19,996 days).
Specimen HCM-BROD-0011-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 25.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09353e02-431a-4f84-aa88-fdae8f73c504.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0011-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0011-C71-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e630f1fa-d0c2-4a6b-9cb5-fd7c3ca697e6

The open-access MAF lists 58 somatic variants for this specimen: 33 protein-altering or splice-affecting, 16 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 16, Intron 5, RNA 3, Nonsense Mutation 3, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1746-1G>C p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 171/364 reads (47%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- SMC1A | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs587784422, COSV59132231; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1836C>A p.C612* | Nonsense Mutation (SNP) | VAF 68/235 reads (29%) | catalogued as COSV51846588; called by muse, mutect2, varscan2
- ACO2 | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.078); catalogued as COSV99346742; called by muse, mutect2, varscan2
- ARMC5 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767369427, COSV51659395; called by muse, mutect2, varscan2
- CCDC168 | c.8090C>A p.A2697D | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV70555196; called by muse, mutect2
- L3MBTL1 | c.115G>A p.A39T (on ENST00000418998 / NM_001377303.1; = p.A17T on NM_032107.5) | Missense Mutation (SNP) | VAF 222/545 reads (41%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.02); catalogued as rs1397260921, COSV64231124; called by muse, mutect2, varscan2
- NGFR | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 268/584 reads (46%) | catalogued as rs757264010; called by muse, mutect2, varscan2
- PAPPA2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 111/198 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs755342431, COSV62774296, COSV62782315; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs565392562, COSV53447756; called by muse, mutect2, varscan2
- SLC6A6 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 191/409 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1471241843, COSV62649040; called by muse, mutect2, varscan2
- UBQLN3 | c.1655C>T p.T552M | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs148446760; called by muse, mutect2, varscan2
- ADAM18 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.444); called by muse, mutect2
- BHMT | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 150/352 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CC2D1A | c.1666G>C p.D556H | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CDH15 | c.1792G>C p.G598R | Missense Mutation (SNP) | VAF 200/422 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DPYSL2 | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.401); called by muse, mutect2
- DUS4L-BCAP29 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 63/360 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRMD1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 116/279 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KRTAP13-4 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 86/252 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MADD | c.4123C>A p.L1375M | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMP24 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 147/299 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NCAM2 | c.1169A>T p.Q390L | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- P2RY2 | c.1039C>T p.Q347* | Nonsense Mutation (SNP) | VAF 43/69 reads (62%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.1030A>C p.N344H | Missense Mutation (SNP) | VAF 13/298 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POM121C | c.3151T>C p.S1051P (on ENST00000607367; = p.S809P on NM_001099415.3) | Missense Mutation (SNP) | VAF 91/639 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RYR2 | c.8935C>T p.R2979C | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN11A | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLX4 | c.4065_4066del p.P1356Afs*35 | Frame Shift Del (DEL) | VAF 42/172 reads (24%) | called by pindel, varscan2
- SVEP1 | c.9338C>T p.P3113L | Missense Mutation (SNP) | VAF 86/154 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBL1Y | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 19/437 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- TCF12 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 263/386 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC5 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2
- AOX1 | c.3204G>A p.S1068= | Silent (SNP) | VAF 70/165 reads (42%) | catalogued as rs745437388, COSV53497005; called by muse, mutect2, varscan2
- CNTNAP2 | c.429C>T p.D143= | Silent (SNP) | VAF 243/793 reads (31%) | catalogued as rs866657669; called by muse, mutect2, varscan2
- COPG1 | c.1092C>A p.I364= | Silent (SNP) | VAF 61/267 reads (23%) | called by muse, mutect2, varscan2
- DNAH3 | c.5514G>A p.E1838= | Silent (SNP) | VAF 80/379 reads (21%) | called by muse, mutect2, varscan2
- FREM3 | c.1269G>A p.V423= | Silent (SNP) | VAF 9/214 reads (4%) | called by muse, mutect2
- GREB1L | c.2424T>C p.I808= | Silent (SNP) | VAF 74/146 reads (51%) | called by muse, mutect2, varscan2
- KRTAP10-3 | c.327C>T p.C109= | Silent (SNP) | VAF 289/961 reads (30%) | called by muse, mutect2, varscan2
- LILRA1 | c.879C>T p.G293= | Silent (SNP) | VAF 272/990 reads (27%) | catalogued as COSV52179467; called by muse, mutect2, varscan2
- MAGEC3 | c.30T>C p.D10= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- MMEL1 | c.798C>T p.N266= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs576993818; called by muse, mutect2, varscan2
- PTPRB | c.786T>C p.P262= | Silent (SNP) | VAF 235/494 reads (48%) | called by muse, mutect2, varscan2
- SLC13A4 | c.150G>A p.S50= | Silent (SNP) | VAF 94/712 reads (13%) | catalogued as rs150811537; called by muse, mutect2, varscan2
- SLC25A46 | c.165G>A p.L55= | Silent (SNP) | VAF 143/595 reads (24%) | catalogued as rs1561596079; called by muse, mutect2, varscan2
- TRBV30 | c.48C>A p.V16= | Silent (SNP) | VAF 52/222 reads (23%) | catalogued as rs1468498519; called by mutect2, varscan2
- UBE2NL | c.285G>A p.K95= | Silent (SNP) | VAF 242/242 reads (100%) | called by muse, mutect2, varscan2
- UTS2R | c.120C>T p.T40= | Silent (SNP) | VAF 192/427 reads (45%) | catalogued as rs377274020, COSV57453005; called by muse, mutect2, varscan2
- AC024940.1 | n.4294C>A | RNA (SNP) | VAF 171/362 reads (47%) | called by muse, mutect2, varscan2
- BDH1 | c.562+14G>A | Intron (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- DAZAP1 | c.30-42G>T | Intron (SNP) | VAF 178/390 reads (46%) | called by muse, mutect2, varscan2
- E4F1 | c.1057-66G>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2357A>G | 3'UTR (SNP) | VAF 174/557 reads (31%) | called by muse, mutect2, varscan2
- GABRA2 | c.1060-5615C>G | Intron (SNP) | VAF 40/55 reads (73%) | catalogued as rs1401252915; called by muse, mutect2, varscan2
- KNOP1P1 | n.423G>T | RNA (SNP) | VAF 86/195 reads (44%) | called by muse, mutect2, varscan2
- MYADML | n.1174T>C | RNA (SNP) | VAF 117/254 reads (46%) | called by muse, mutect2, varscan2
- ZNF789 | c.265+1100A>G | Intron (SNP) | VAF 53/409 reads (13%) | catalogued as rs1166346081; called by muse, mutect2, varscan2
